TCGA case TCGA-NC-A5HP — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Washington University - CHUV. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4a95ce25-d06a-499d-b7ee-aff5ee94d4f1

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Switzerland; Age at index: 69 years; Vital status: Dead; Days to death: 770 days (2.1 years).

Diagnoses (5)
1. Squamous cell carcinoma, keratinizing, NOS (the primary disease): ICD-O-3 morphology code: 8071/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 69.2 years (25,286 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M1b; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 770 days (2.1 years); Sites of involvement: Peripheral Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 52 days; Days to treatment end: 113 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Days to treatment start: 52 days; Days to treatment end: 113 days; Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Days to treatment start: 358 days; Days to treatment end: 448 days (1.2 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 485 days (1.3 years); Days to treatment end: 485 days (1.3 years); Treatment dose: 20 Gy; Treatment outcome: Progressive Disease; Number of fractions: 1; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride; Days to treatment start: 540 days (1.5 years); Days to treatment end: 632 days (1.7 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Days to treatment start: 632 days (1.7 years); Treatment outcome: Treatment Ongoing.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, keratinizing, NOS). Age at diagnosis: 70.1 years (25,603 days); Days to diagnosis: 317 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.
3. Metastasis of diagnosis 1 (Squamous cell carcinoma, keratinizing, NOS). Age at diagnosis: 70.4 years (25,709 days); Days to diagnosis: 423 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 485 days (1.3 years); Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
4. Metastasis of diagnosis 1 (Squamous cell carcinoma, keratinizing, NOS). Age at diagnosis: 70.7 years (25,826 days); Days to diagnosis: 540 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.
5. Metastasis of diagnosis 1 (Squamous cell carcinoma, keratinizing, NOS). Age at diagnosis: 71.0 years (25,918 days); Days to diagnosis: 632 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site.

Follow-up (6 entries)
- Day 317 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 317 days; Evidence of progression type: Convincing Image Source.
- Day 423 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 423 days (1.2 years); Evidence of progression type: Convincing Image Source.
- Day 540 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 540 days (1.5 years); Evidence of progression type: Convincing Image Source.
- Day 632 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 632 days (1.7 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 730 days (2.0 years); Disease response: With Tumor.
- Days to follow up: 770 days (2.1 years); Disease response: With Tumor.

Other clinical attributes
- FEV1/FVC before bronchodilator (%): 99; FEV1 before bronchodilator (% of reference): 87.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 50.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-NC-A5HP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 140 mg.
  Slide TCGA-NC-A5HP-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 75; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-NC-A5HP-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-NC-A5HP-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 2; Anatomic organ subdivision: L-Upper; Location lung parenchyma: Peripheral Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Drug treatment 2: Pharmaceutical therapy drug name: Navelbine; Treatment best response: Clinical Progressive Disease.
- Drug treatment 4: Pharmaceutical therapy drug name: Gemzar; Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: Yes.
- Follow-up form 1, New neoplasm event types: New tumor event type: Distant Metastasis.
- Follow-up form 1, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 770 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 770 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 317 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-NC-A5HP-01A-11D-A26L-01): tumor purity 0.53, ploidy 3.67, whole-genome doublings 1.
